TCGA case TCGA-Q2-A5QZ — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: University of Oklahoma HSC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4a9a3a6d-090a-4c26-b16c-d65055f05628

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 61.7 years (22,531 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T3a; AJCC clinical N: NX; AJCC clinical M: MX; AJCC pathologic T: T3a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 428 days (1.2 years).
   Pathology details: Consistent pathology review: Yes; Prcc type: Type 2.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 62.8 years (22,943 days); Days to diagnosis: 412 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 412 days (1.1 years); Treatment anatomic sites: Distant Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 412 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 412 days (1.1 years).
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Post Adjuvant Therapy.
- Follow-up contacts recording only the day: day 57, day 428.

Molecular and laboratory tests
- Calcium: Low.
- Leukocytes: Elevated.
- Hemoglobin: Low.
- Platelets: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79.5 kg; Height: 162.56 cm; BMI: 30.1.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 15; Tobacco smoking onset year: 1998; Tobacco smoking quit year: 2013.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-Q2-A5QZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 350 mg.
  Slide TCGA-Q2-A5QZ-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 30; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 2.
- Sample TCGA-Q2-A5QZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-Q2-A5QZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 4; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 428 days; disease-specific survival: no event (censored), 428 days; disease-free interval: event (new tumor event after initially disease-free), 412 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 412 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-Q2-A5QZ-01A-11D-A28F-01): tumor purity 0.7, ploidy 1.78, whole-genome doublings 0.
